CCDI case PBCPSX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6291cc30-45c0-485a-8c07-b3fc0780fa9d

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.5 years (1,642 days).

Biospecimens (3 samples)
- Sample 0DWYUV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWYVD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWYWM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
